Somatic mutation profile of tumor specimen TCGA-X7-A8M0-01A (aliquot TCGA-X7-A8M0-01A-11D-A423-09) from TCGA case TCGA-X7-A8M0, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 61.9 years (22,596 days).
Specimen TCGA-X7-A8M0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3662c890-82f6-45f6-b113-47a1333c9cc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8M0-10A (Blood Derived Normal), aliquot TCGA-X7-A8M0-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f53a50f4-36d1-4d36-9444-b4e6ad07f6b5

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Splice Site 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 55/404 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- RAPGEF4 | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs376593491; called by mutect2, varscan2
- TDRD9 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV59150645; called by muse, mutect2, varscan2
- COL6A6 | c.2786T>C p.L929P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD2 | c.1849C>A p.H617N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2
- NDST4 | c.2116-1G>A p.X706_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- NEXMIF | c.3020G>T p.C1007F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- OBSCN | c.9098A>G p.Y3033C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RNF213 | c.2986G>T p.E996* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- RNF8 | c.983A>T p.E328V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2
- SORCS1 | c.3304G>T p.A1102S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4A16 | c.825T>C p.I275= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV59044619; called by muse, mutect2, varscan2
